Gene-level copy-number profile of tumor specimen TCGA-XF-A9T4-01A from TCGA case TCGA-XF-A9T4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 48.5 years (17,728 days).
Specimen TCGA-XF-A9T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.41ba72dd-1519-4d71-a57c-5b0e82534e37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9T4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb658df0-0d82-4b25-aa9e-5bcc1de9c102

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 3,057; copy number 2: 55,030; copy number 3: 4; copy number 4: 1,513; copy number 5: 53; copy number 6: 36; copy number 9: 107; copy number 10: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9T4-01A-11D-A390-01): tumor purity 0.78, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,029,594, 10 genes (within-gene range 0–3): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT.
- chr9:22,203,990–22,455,740, 2 genes: AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 201 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:1,328,664–1,550,103, 3 genes, copy number 6: AL358934.1, RNA5SP279, AL358053.1.
- chr9:3,684,076–4,348,392, 6 genes, copy number 6 (within-gene range 1–6): AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1, AL162419.1.
- chr9:4,679,559–4,742,043, 2 genes, copy number 6 (within-gene range 1–6): CDC37L1, AK3.
- chr9:5,334,930–5,629,748, 9 genes, copy number 5: RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1.
- chr9:6,720,863–7,175,648, 1 gene, copy number 5 (within-gene range 1–5): KDM4C.
- chr9:6,834,456–7,203,458, 3 genes, copy number 5: ACTG1P14, AL513412.1, AL161443.1.
- chr9:11,618,496–13,836,571, 19 genes, copy number 6 (within-gene range 1–6): AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1.
- chr9:17,134,982–17,797,124, 4 genes, copy number 5: CNTLN, SAMM50P1, SH3GL2, PABPC1P11.
- chr9:19,108,375–19,895,973, 16 genes, copy number 5: PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2, AL158077.1.
- chr9:23,291,544–24,592,104, 13 genes, copy number 5 (within-gene range 1–5): AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr9:27,391,734–27,397,563, 1 gene, copy number 6: AL163192.1.
- chr9:27,829,276–28,670,286, 3 genes, copy number 5–6 (within-gene range 1–6): AL360014.1, AL353746.1, LINGO2.
- chr9:28,539,735–28,888,955, 4 genes, copy number 6: AL445526.1, KCTD10P1, MIR876, MIR873.
- chr9:37,650,954–37,746,904, 1 gene, copy number 5 (within-gene range 1–5): FRMPD1.
- chr9:37,753,803–37,867,666, 4 genes, copy number 5: TRMT10B, EXOSC3, DCAF10, AL138752.1.
- chr11:54,591,480–54,660,596, 5 genes, copy number 10: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P.
- chr11:65,745,729–66,049,161, 24 genes, copy number 9: AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1, CFL1, SNX32, MUS81, EFEMP2, CTSW, FIBP, CCDC85B, FOSL1, C11orf68, DRAP1, TSGA10IP, SART1, AP006287.1, EIF1AD, BANF1, CST6, CATSPER1, GAL3ST3, AP006287.3.
- chr11:68,870,664–71,670,297, 81 genes, copy number 9 (broad region; genes not listed).
- chr11:71,690,453–71,705,404, 2 genes, copy number 9: SNRPCP14, AP003498.1.

Autosomal genes at a single copy (total copy number 1): 677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
